FM case AD1231 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon.
https://portal.gdc.cancer.gov/cases/6f0b8781-ad66-4b3d-8fbc-af2230cdc632

Female, 37.4 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the appendix. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Tumor.
